Somatic mutation profile of tumor specimen MBCProject_0786_T1_WES (aliquot MBCProject_0786_T1_WES_1) from CMI case MBCProject_0786, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 51.4 years (18,762 days).
Specimen MBCProject_0786_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Axilla; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a65a7cf1-9f3a-4c36-8441-4458a21023fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0786_SALIVA (Saliva), aliquot MBCProject_0786_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41235d3b-8a78-4cf2-a1c3-5dbc86646704

The open-access MAF lists 79 somatic variants for this specimen: 50 protein-altering or splice-affecting, 18 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 18, 3'UTR 4, Intron 3, 5'Flank 2, Nonsense Mutation 1, Splice Region 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 15/107 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.584T>G p.I195S | Missense Mutation (SNP) | VAF 55/457 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs1434150093, COSV67125673, COSV67136081, COSV67136513; called by muse, mutect2, varscan2
- ANP32E | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 56/235 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553840925, COSV58483264; called by muse, mutect2, varscan2
- CCDC39 | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99870115; called by muse, mutect2, varscan2
- CERS2 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 28/208 reads (13%) | catalogued as rs779040680, COSV99645031; called by muse, mutect2, varscan2
- CRY1 | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.035); catalogued as COSV50482032; called by muse, mutect2
- FCGR3A | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 102/1174 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs760902695, COSV63459949; called by muse, mutect2
- HK2 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 67/601 reads (11%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.005); catalogued as COSV51878239, COSV51878851; called by muse, mutect2, varscan2
- HTR3E | c.95G>T p.C32F (on ENST00000415389 / NM_001256613.1; = p.C47F on NM_182589.2) | Missense Mutation (SNP) | VAF 44/410 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373215721; called by muse, mutect2
- KIF5C | c.152G>C p.R51T | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as rs367955770, COSV70535492, COSV70537284; called by mutect2, varscan2
- LBX1 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 48/460 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.119); catalogued as rs1418164651, COSV100929899; called by muse, mutect2, varscan2
- MUC4 | c.12505G>T p.V4169L | Missense Mutation (SNP) | VAF 74/484 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.25); catalogued as rs1386507889; called by muse, varscan2
- NEXMIF | c.3191G>A p.R1064H | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770464262, COSV50029704; called by muse, mutect2, varscan2
- OR5M3 | c.484T>C p.Y162H | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.215); catalogued as rs1368179106; called by muse, mutect2
- PCYT2 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752074029, COSV58712642; called by muse, mutect2, varscan2
- RERE | c.3502G>A p.E1168K | Missense Mutation (SNP) | VAF 37/638 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as rs1338323313, COSV61938715; called by muse, mutect2
- RFXAP | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.4); catalogued as rs1290515755; called by muse, mutect2, varscan2
- RPL26 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV53446831; called by muse, mutect2
- RUFY3 | c.570C>A p.L190= | Splice Region (SNP) | VAF 7/51 reads (14%) | catalogued as COSV56913605; called by muse, mutect2, varscan2
- SOX10 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 21/218 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs774135262; ClinVar: uncertain significance; called by muse, mutect2
- TNR | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs954788201, COSV54881961, COSV54911641; called by muse, mutect2
- AIFM1 | c.1724G>T p.G575V | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CASK | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.07); called by muse, mutect2
- CCDC168 | c.13510G>A p.D4504N | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- CDH8 | c.1889G>A p.C630Y | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- CHMP5 | c.619C>G p.L207V | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.079); called by muse, mutect2
- COPB1 | c.876G>C p.E292D | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- DNAH17 | c.12344T>C p.M4115T | Missense Mutation (SNP) | VAF 24/317 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.341); called by muse, mutect2
- DOCK5 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- EDA2R | c.505C>T p.H169Y | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.068); called by muse, mutect2
- FUT10 | c.1435_*4delinsAAAAAAAAAA | Missense Mutation (ONP) | VAF 5/61 reads (8%) | called by mutect2*, pindel
- HDAC7 | c.1961C>T p.S654F (on ENST00000427332; = p.S693F on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2
- HS6ST3 | c.1048T>G p.F350V | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IFT74 | c.1774G>A p.D592N | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ITGAE | c.3109C>G p.Q1037E | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2
- KDM2A | c.1700G>A p.R567K | Missense Mutation (SNP) | VAF 51/591 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- KNTC1 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- KRIT1 | c.32A>G p.Y11C | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2
- MDH2 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 21/256 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.564); called by muse, mutect2
- MGAT5B | c.2300C>T p.S767F (on ENST00000569840 / NM_001199172.2; = p.S765F on NM_144677.3) | Missense Mutation (SNP) | VAF 44/327 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PCDHA6 | c.434C>G p.S145C | Missense Mutation (SNP) | VAF 12/313 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- PLEKHA4 | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); called by muse, mutect2
- SNX8 | c.788T>C p.I263T | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- STMN2 | c.497A>C p.E166A | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.056); called by muse, mutect2
- SYDE2 | c.2668A>G p.T890A | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); called by muse, mutect2
- TTC37 | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- YARS1 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- ZC3H13 | c.1996G>C p.D666H | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.769); called by muse, mutect2
- ZMIZ1 | c.1806G>C p.W602C | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2
- AARS1 | c.882C>A p.A294= | Silent (SNP) | VAF 44/632 reads (7%) | called by muse, mutect2
- CFAP74 | c.864G>A p.L288= | Silent (SNP) | VAF 31/248 reads (13%) | catalogued as rs201966761, COSV54571581; called by muse, mutect2, varscan2
- CIT | c.2775C>T p.L925= | Silent (SNP) | VAF 35/199 reads (18%) | called by muse, mutect2, varscan2
- DMD | c.5544G>A p.K1848= | Silent (SNP) | VAF 30/256 reads (12%) | catalogued as COSV100822571, COSV100823989; called by muse, mutect2, varscan2
- EIF2AK1 | c.1892G>A p.*631= | Silent (SNP) | VAF 13/176 reads (7%) | catalogued as COSV52238881; called by muse, mutect2
- FAM71A | c.1221G>A p.Q407= | Silent (SNP) | VAF 16/136 reads (12%) | called by muse, mutect2, varscan2
- LRCH4 | c.1215G>A p.P405= | Silent (SNP) | VAF 22/210 reads (10%) | catalogued as rs756370433; called by muse, mutect2
- NUP188 | c.3948C>G p.L1316= | Silent (SNP) | VAF 32/386 reads (8%) | catalogued as COSV65361558; called by muse, mutect2
- OR4C16 | c.276C>T p.F92= | Silent (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- PROKR2 | c.876C>T p.Y292= | Silent (SNP) | VAF 88/789 reads (11%) | catalogued as rs747977707, COSV54088713; called by muse, mutect2, varscan2
- RPAP2 | c.1809C>T p.I603= | Silent (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- SIL1 | c.435G>A p.E145= | Silent (SNP) | VAF 36/358 reads (10%) | called by muse, mutect2
- SLC5A2 | c.1179G>A p.S393= | Silent (SNP) | VAF 36/322 reads (11%) | catalogued as COSV57891155; called by muse, mutect2, varscan2
- SLC6A8 | c.66C>T p.L22= | Silent (SNP) | VAF 70/551 reads (13%) | catalogued as COSV53471491; called by muse, mutect2, varscan2
- SLC8A2 | c.327C>T p.I109= | Silent (SNP) | VAF 62/644 reads (10%) | catalogued as rs267605557; called by muse, mutect2
- WDR90 | c.1383C>T p.F461= | Silent (SNP) | VAF 10/219 reads (5%) | called by muse, mutect2
- WNT6 | c.414C>T p.R138= | Silent (SNP) | VAF 13/127 reads (10%) | catalogued as rs750721965, COSV99293319; called by muse, mutect2, varscan2
- ZNF174 | c.921G>C p.L307= | Silent (SNP) | VAF 24/230 reads (10%) | called by muse, mutect2, varscan2
- ARHGAP36 | c.-148G>A | 5'UTR (SNP) | VAF 12/57 reads (21%) | catalogued as COSV52273910, COSV99357875; called by muse, mutect2, varscan2
- DNAJC11 | c.*1003G>A | 3'UTR (SNP) | VAF 24/264 reads (9%) | catalogued as rs1211448689, COSV50011138; called by muse, mutect2
- EIF2AK1 | c.1764+261G>A | Intron (SNP) | VAF 18/209 reads (9%) | called by muse, mutect2
- EPB41L3 | chr18:5630611 C>G | 5'Flank (SNP) | VAF 8/68 reads (12%) | called by muse, varscan2
- NPY6R | n.1149C>T | RNA (SNP) | VAF 26/274 reads (9%) | called by muse, mutect2
- PABPC1L | c.*59C>T | 3'UTR (SNP) | VAF 16/217 reads (7%) | catalogued as rs1293581478; called by muse, mutect2
- PRX | c.381+21C>T | Intron (SNP) | VAF 16/166 reads (10%) | catalogued as rs146965324; called by muse, mutect2
- SFRP1 | c.544+1828T>C | Intron (SNP) | VAF 36/406 reads (9%) | called by muse, mutect2
- ZNF384 | c.*85C>T | 3'UTR (SNP) | VAF 20/148 reads (14%) | catalogued as rs568681316; called by muse, varscan2
- ZNF41 | chrX:47483863 C>T | 5'Flank (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- ZNF99 | c.*3217A>G | 3'UTR (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
